CCDI case PBCEPN — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Adrenal gland.
https://portal.gdc.cancer.gov/cases/d623aba2-d662-4cf7-bf5d-d2c5dcf76a25

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Pheochromocytoma, NOS: ICD-O-3 morphology code: 8700/0; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 12.5 years (4,578 days).

Biospecimens (3 samples)
- Sample 0DR6XM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DR6XY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DR6Y8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
